Surgical pathology report (de-identified scan), TCGA case TCGA-67-3774, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-3774-01A (Primary Tumor).

[page 1 of 4]
PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

LUNG-LOBECTOMY, RESECTION, REGIONAL LYMPH

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: LEFT LUNG CA

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "9L" and consists of a yellow tan soft tissue fragment measuring 0.8 cm in greatest dimension; submitted in toto; 1 (1) labeled "FSP" and used for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor. [REDACTED]

B. The specimen is submitted fresh as "neck 5th rib" and consists of a segment of rib measuring 2 cm in length and 1.2 cm in diameter. The specimen is bisected longitudinally and submitted in toto; 2 (1) for decalcification.

C. The specimen is submitted fresh as "neck of 6th rib" and consists of a segment of rib measuring 1.2 cm in length and 1.3 cm in diameter. The specimen is bisected and submitted in toto; 2 (1) for decalcification.

D. The specimen is submitted fresh as "left lower lobe lung" and consists of a lobe of lung weighing 157 gms and measuring 13.5 x 7.5 x 7 cm in dimension. There is a bifurcated stapled bronchial margin measuring 0.4 cm and 1.5 cm in diameter and three stapled vessel margins ranging 0.4 cm to 0.7 cm in diameter. There are several anthracotic nodes clustered at the hilum ranging 0.3 cm to 1.5 cm in greatest dimension. The pleural surface is purple tan with membranous adhesions. A firm mass is palpated on the lateral aspect. Sectioning reveals an underlying firm

[page 2 of 4]
GROSS DESCRIPTION

(Continued)

tan tumor with poorly defined borders which abuts the inked (black) pleural surface with a gross dimension of 3.3 x 3 x 1.5 cm approaching 3 cm of the stapled bronchial margin. The remainder of the pulmonary parenchyma is pink to deep red and airless. Representative sections are submitted; multiple (12) labeled as follows:

Cassette D1:	Bronchial margin.
Cassette D2:	Vessel margins.
Cassette D3:	Nodules found at the hilum.
Cassettes D4 through D9:	Representative tumor in consecutive cassettes.
Cassettes D10 and D11:	Representative bronchial tree and vessels adjacent to the tumor.
Cassette D12:	Representative uninvolved pulmonary parenchyma.

Please note: A portion of tissue is submitted for TCGA studies.

FINAL DIAGNOSIS

- A. LYMPH NODE, 9L (BIOPSY):
- SINGLE LYMPH NODE SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR (0/1).
- B. NECK OF 5TH RIB (RESECTION):
- RIB WITH HEMATOPOIETIC MARROW; NEGATIVE FOR TUMOR.
- C. NECK OF 6TH RIB (RESECTION):
- RIB WITH HEMATOPOIETIC MARROW; NEGATIVE FOR TUMOR.
- D. LEFT LUNG, LOWER LOBE (LOBECTOMY):
- INFILTRATING, MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH FOCAL BRONCHOALVEOLAR FEATURES (3.3 CM).
- TUMOR CLOSELY APPROACHES, BUT DOES NOT APPEAR TO INVADE, THE VISCERAL PLEURA.
- NO VASCULAR INVASION IS SEEN.
- BRONCHIAL AND VASCULAR MARGINS AND SEVEN (7) LOBAR LYMPH NODES ARE NEGATIVE FOR TUMOR.
- BACKGROUND LUNG SHOWS SCATTERED SMALL NON-CASEATING GRANULOMAS ASSOCIATED WITH FRAGMENTS OF WEAKLY POLARIZABLE MATERIAL.

COMMENT: SPECIAL STAINS (AFB, GMS) WILL BE EXAMINED ON A SECTION SHOWING GRANULOMAS. ADDENDUM TO FOLLOW.

[page 3 of 4]
SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
LATERALITY: LEFT
TUMOR SITE: LOWER LOBE
TUMOR SIZE: 3.3 X 3 X 1.5 CM
HISTOLOGIC TYPE: ADENOCARCINOMA
HISTOLOGIC GRADE: II
EXTENT OF INVASION: CONFINED TO LUNG
EXTENTION TO PLEURA/OTHER STRUCTURES: NOT SEEN
ADDITIONAL PERTINENT FINDINGS: FOCAL BRONCHOALVEOLAR FEATURES

MARGINS:

BRONCHIAL: NEGATIVE
PARENCHYMAL: N/A
VASCULAR: NEGATIVE
DISTANCE TO PERTINENT MARGIN(S): 3 CM TO BRONCHIAL MARGIN

VENOUS INVASION: NOT SEEN
ARTERIAL (LARGE VESSEL) INVASION: NOT SEEN

LYMPH NODES [REDACTED] - [REDACTED]
N1 - # INVOLVED/# EXAMINED: 0/7
N2 - # INVOLVED/#EXAMINED: 0/MULTIPLE
N3 - # INVOLVED/# EXAMINED: 0/0

OTHER FINDINGS: SCATTERED SMALL NON-CASEATING GRANULOMAS

pTNM STAGE (AJCC 7TH EDITION): pT2a pN0 MX (STAGE IB)

ADDENDUM

NO ORGANISMS ARE IDENTIFIED ON SPECIAL STAINS (AFB, GMS) PERFORMED ON A REPRESENTATIVE SECTION FROM PART "D".

Source: NCI Genomic Data Commons file 84f7f0c0-b79b-4568-9501-434e9ef36940 (TCGA-67-3774.A1D72B00-7384-4A8F-B335-5BEB9AE078FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).